Somatic mutation profile of tumor specimen TCGA-DV-5568-01A (aliquot TCGA-DV-5568-01A-01D-1534-10) from TCGA case TCGA-DV-5568, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 26.6 years (9,714 days).
Specimen TCGA-DV-5568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3404f22a-b60a-48ac-afe5-843b4cbf7617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5568-10A (Blood Derived Normal), aliquot TCGA-DV-5568-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f767fc2a-94f5-48c2-b957-2b892ef0c1f3

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.528T>G p.Y176* | Nonsense Mutation (SNP) | VAF 186/548 reads (34%) | catalogued as rs1057522285, CM020756, CM033668, CX135246, COSV64292861; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP5 | c.2980A>T p.I994F | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as COSV61534550; called by muse, mutect2, varscan2
- DSG2 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV55197874; called by muse, mutect2, varscan2
- FAM135B | c.3790+2T>A p.X1264_splice | Splice Site (SNP) | VAF 58/235 reads (25%) | catalogued as COSV99427023; called by muse, mutect2, varscan2
- MIA3 | c.1513A>T p.N505Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60511187; called by muse, mutect2, varscan2
- OR4M1 | c.590T>C p.L197S | Missense Mutation (SNP) | VAF 147/1303 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60059502; called by muse, mutect2, varscan2
- PLEKHG3 | c.1458G>T p.E486D (on ENST00000394691; = p.E542D on NM_001308147.2) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55978518; called by muse, mutect2, varscan2
- SLCO4C1 | c.1882A>G p.I628V | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs757462169, COSV60513891; called by muse, mutect2
- SPATA25 | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99510123; called by muse, mutect2
- SRRT | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61451567; called by muse, mutect2, varscan2
- STARD13 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368835264; called by muse, mutect2
- CCNF | c.1048del p.Y350Tfs*23 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- MAST1 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- NBPF11 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, varscan2
- PIK3R1 | c.1365_1373del p.F456_E458del (on ENST00000521381 / NM_181523.3; = p.F186_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 72/301 reads (24%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.2622G>A p.L874= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100410393; called by muse, varscan2
- CHRNB4 | c.369G>A p.G123= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55715301; called by muse, mutect2, varscan2
- RHOT2 | c.399C>T p.P133= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV53467735; called by muse, mutect2, varscan2
- VCAN | c.8142A>G p.K2714= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99427125; called by muse, mutect2
- ZNF26 | c.885T>C p.F295= | Silent (SNP) | VAF 64/222 reads (29%) | called by muse, mutect2, varscan2
